Gene-level copy-number profile of tumor specimen ALCH-AEUR-TTP1-A from ALCHEMIST case ALCH-AEUR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.5 years (25,767 days).
Specimen ALCH-AEUR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1b92a3b9-34a1-4c04-93c6-6803d73f650a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEUR-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,720 have no estimate.
https://portal.gdc.cancer.gov/files/9907cb62-9f8a-4a2d-a380-d488305d9781

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 7,103; copy number 2: 49,694; copy number 3: 2,095; copy number 4: 4.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:99,481,169–99,535,044, 1 gene (within-gene range 0–1): CCNK.
- chr14:99,512,501–99,513,576, 1 gene (within-gene range 0–1): AL110504.1.
- chr16:88,382,959–88,440,757, 1 gene: ZNF469.
- chr19:17,281,645–17,310,236, 4 genes (within-gene range 0–2): ANKLE1, ABHD8, MRPL34, AC010463.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 4,254. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
